Somatic mutation profile of tumor specimen 0DXJH6 from CCDI case PBCRIF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 20.1 years (7,333 days).
Specimen 0DXJH6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af737591-0089-41ea-9849-a8be358da548.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXJEI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07f25050-df5d-4d58-bff4-fdda9574b654

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 38/1051 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 42/1332 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 38/1386 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- KIAA0408 | c.1519A>T p.N507Y | Missense Mutation (SNP) | VAF 55/993 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2
- EMILIN3 | c.-86G>T | 5'UTR (SNP) | VAF 3/17 reads (18%) | called by muse, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 20/330 reads (6%) | called by muse, mutect2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 3/38 reads (8%) | catalogued as COSV55814242; called by muse, mutect2
